Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8677, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8677-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

[Redacted] Case ID	[Redacted] ID	Excision date
[Redacted]	[Redacted]	[Redacted]

[page 2 of 3]
Gross Description	Microscopic Description	Diagnosis Details
Stomach with saucer-like tumor up to 7.5 cm in size, with whole wall thickness invasion. In the fatty tissue there are dense hyperemic lymph nodes up to 1 cm in size. Omentum	Gastric adenocarcinoma, G-3, with invasion into the fatty tissue and spread to two adjacent lymph nodes. Eight from fifteen examined lymph nodes demonstrated metastasis.	Tumor Features: Ulcerated, Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Absent, Treatment Effect:

[page 3 of 3]
Comments	Formatted Path Report
Original records say N2.	STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Antrum Tumor size: 0 x 0 x 7.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Subserosa Lymph nodes: 8/15 positive for metastasis (Greater and lesser curvature 8/15) Lymphatic invasion: Not specified Venous invasion: Absent Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

Source: NCI Genomic Data Commons file 8b8664d4-e466-4282-a758-440bd1c9aa29 (TCGA-BR-8677.2004E918-CB0B-463C-B487-625F96F8D3C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).